Somatic mutation profile of tumor specimen TCGA-QR-A705-01A (aliquot TCGA-QR-A705-01A-11D-A35D-08) from TCGA case TCGA-QR-A705, project TCGA-PCPG (Pheochromocytoma and Paraganglioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Extra-adrenal paraganglioma, NOS; Tissue or organ of origin: Heart; Age at diagnosis: 63.2 years (23,086 days).
Specimen TCGA-QR-A705-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 594ce26d-0599-44da-9ca6-dd08414f7176.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-QR-A705-10A (Blood Derived Normal), aliquot TCGA-QR-A705-10A-01D-A35B-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/203795b8-4ef2-4f58-a4cc-f0c28b61857d

The open-access MAF lists 9 somatic variants for this specimen: 5 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Silent 3, RNA 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ZEB1 | c.2682G>T p.K894N | Missense Mutation (SNP) | VAF 12/125 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV100313794; called by muse, mutect2, varscan2
- DNAAF5 | c.1624A>G p.T542A | Missense Mutation (SNP) | VAF 33/95 reads (35%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.621); called by muse, mutect2, varscan2
- FBXO32 | c.424C>G p.Q142E | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- KCNK9 | c.146_166del p.K49_S55del | In Frame Del (DEL) | VAF 8/37 reads (22%) | called by mutect2, pindel
- PTGS1 | c.857T>C p.V286A | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.693); called by muse, mutect2, varscan2
- DELE1 | c.423A>G p.Q141= | Silent (SNP) | VAF 4/71 reads (6%) | catalogued as rs1385946982; called by muse, mutect2
- PLCL1 | c.510A>G p.K170= | Silent (SNP) | VAF 5/80 reads (6%) | called by muse, mutect2
- SERPINB2 | c.477A>G p.L159= | Silent (SNP) | VAF 36/103 reads (35%) | called by muse, mutect2, varscan2
- GLRXP3 | n.67T>C | RNA (SNP) | VAF 9/71 reads (13%) | called by muse, mutect2, varscan2
